Somatic mutation profile of tumor specimen TCGA-G9-6365-01A (aliquot TCGA-G9-6365-01A-11D-1786-08) from TCGA case TCGA-G9-6365, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.8 years (26,207 days).
Specimen TCGA-G9-6365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a31890e-3054-40f7-965c-419fcf640f27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6365-10A (Blood Derived Normal), aliquot TCGA-G9-6365-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de4e78da-1e84-41bc-a5b7-9c930f60ed0f

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, In Frame Del 1, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL1 | c.133T>C p.C45R | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52814099; called by muse, mutect2
- BRD9 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV51319725, COSV51321615; called by muse, mutect2, varscan2
- DLGAP2 | c.2375C>T p.T792M | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs368030190, COSV70097183; called by muse, mutect2, varscan2
- FGA | c.1729T>C p.S577P | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV57395169, COSV57399925; called by muse, mutect2, varscan2
- GCK | c.1253+2T>C p.X418_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | catalogued as COSV56267730; called by muse, mutect2, varscan2
- KIAA1217 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762992132, COSV64604437; called by muse, mutect2, varscan2
- LRRC43 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.421); catalogued as COSV60289531; called by muse, mutect2
- OPN5 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV55245138, COSV55246687; called by muse, mutect2, varscan2
- OR2M2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs775272894, COSV62897939; called by muse, mutect2, varscan2
- PCDHB5 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV50649996; called by muse, mutect2, varscan2
- PREX2 | c.828A>T p.K276N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55765116; called by muse, mutect2, varscan2
- SPTA1 | c.1922A>G p.Q641R | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100935553, COSV63751996; called by muse, mutect2
- TAOK1 | c.1882A>C p.N628H | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV55590818; called by muse, mutect2, varscan2
- TTN | c.73600C>T p.P24534S (on ENST00000591111; = p.P17110S on NM_003319.4) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | PolyPhen probably damaging (0.998); catalogued as COSV60001079; called by muse, mutect2
- UBR2 | c.2021_2029del p.L674_N676del | In Frame Del (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel, varscan2
- PCDHGB2 | c.1803C>T p.N601= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs778338184, COSV99531734; called by muse, mutect2, varscan2
- STYXL2 | c.1053C>T p.Y351= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs754343401, COSV54804225; called by muse, varscan2
- AL132655.6 | chr20:58840415 C>T | 5'Flank (SNP) | VAF 33/125 reads (26%) | catalogued as rs373276011; called by muse, mutect2, varscan2
- AL136295.1 | c.-7G>C | 5'UTR (SNP) | VAF 6/72 reads (8%) | catalogued as COSV51660109; called by muse, mutect2
